Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IA, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IA-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT PELVIC LYMPH NODES:
METASTATIC ADENOCARCINOMA IN TWO OF ELEVEN LYMPH NODES WITH EXTRANODAL EXTENSION
(2/11). (SEE COMMENT)
- (B) RIGHT PELVIC LYMPH NODES:
METASTATIC ADENOCARCINOMA IN ONE OF EIGHT LYMPH NODES (1/8). (SEE COMMENT)
- (C) "LEFT PERIVESICLE" LYMPH NODES:
Adipose tissue no lymph nodes or tumor present.
- (D) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

CKE ICD-O-3
Adenocarcinoma, ovarian 8140/3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
9/21/24/13

Entire report and diagnosis completed by

COMMENT

The foci of metastatic carcinoma measure 4.0 mm and 8.0 mm in part A and 4.0 mm in part B.

GROSS DESCRIPTION

(A) LEFT PELVIC LYMPH NODES – Received are multiple fragments of fatty tissue measuring in aggregate (9 x 5 x 2 cm). Dissection reveals multiple possible lymph nodes ranging from 0.4 up to 2.8 cm in their greatest dimension. Possible lymph nodes are entirely submitted in cassettes.

SECTION CODE: A1, three possible lymph nodes; A2, one sectioned possible lymph node; A3, one sectioned possible lymph node; A4, one sectioned possible lymph node; A5, one sectioned possible lymph node; A6, A7, one sectioned possible lymph node; A8, A9, one sectioned possible lymph node; A10, A11, one sectioned possible lymph node; A12-A14, one sectioned possible lymph node.

(B) RIGHT PELVIC LYMPH NODES – Multiple fragments of fatty tissue measuring in aggregate 8.5 x 4.5 x 2 cm. Dissection reveals multiple possible lymph nodes ranging from 0.5 up to 3.3 cm in greatest dimension. Possible lymph nodes are entirely submitted in cassettes.

SECTION CODE: B1, two possible lymph nodes; B2, one sectioned possible lymph node; B3, one sectioned possible lymph node; B4, one sectioned possible lymph node; B5, one sectioned possible lymph node; B6, one sectioned possible lymph node; B7-B10, one sectioned possible lymph node.

(C) LEFT PERIVESICLE LYMPH NODES – Multiple fragments of fatty tissue measuring in aggregate 2.5 x 2.4 x 0.5 cm. Entirely submitted in cassette C.

(D) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

Prostatic cancer.

SNOMED CODES

T-C4600, M-y1976

[page 2 of 4]
[REDACTED]

[REDACTED]

Specimen Date/Time:

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 3 of 4]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(D) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4 + 5). (SEE COMMENT)

TUMOR EXTENDING IN MULTIPLE AREAS INTO EXTRAPROSTATIC TISSUE.

TUMOR INVADING LEFT SEMINAL VESICLE AND LEFT PERIVESICULAR SOFT TISSUE.

FOCAL EXTENSION OF TUMOR TO THE MARGIN OF RESECTION CANNOT BE EXCLUDED.

Right seminal vesicle and segments of vasa deferentia, no tumor present.

SEE PREVIOUS REPORT FOR DIAGNOSIS OF THE PELVIC LYMPH NODES.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in the right anterior, mid anterior, left anterior, left anterolateral, left lateral, left posterolateral, left posterior, mid posterior, right posterior, right posterolateral and right lateral peripheral zone. It is estimated that the tumor occupies approximately 70% of the prostatic volume. The tumor focus measures 4.5 x 3.0 cm in the largest cross-sectional dimension and it is present in three cross sections and extensively in the apex and base regions. The tumor exhibits extraprostatic extension in the left lateral and left posterolateral aspect of the prostate, left superior neurovascular bundle region and posterior surface of the prostate at the base level. At the sites of extraprostatic extension, the margin of resection is free of tumor. The tumor extends in the right posterolateral aspect of the prostate to less than 0.1 mm from the inked surface. Focal marginal involvement cannot be excluded.

The tumor extensively involves the left seminal vesicle including intra and extraprostatic portions.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

[page 4 of 4]
Specimen Date/Time:

(D) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.8 x 3.3 x 3.4 cm, 51 grams, post-fixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate appears more abundant than along the right side. Nodules are palpated on the left and right sides of the prostate. Serial cross sections after fixation demonstrate areas consistent with tumor in the right posterolateral and left posterolateral peripheral zone of the three cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: D1-D3, right seminal vesicle and segment of right vas deferens from the base towards the tip; D4-D6, left seminal vesicle and segment of left vas deferens from the base towards the tip; D7, D8, prostatic base, right border; D9-D12, prostatic base, right posterior border; D13-D22, prostatic base, central portion; D23, D24, prostatic base, left border; D5-D28, prostatic base, left posterior border; D29-D31, apex anterior; D32, D33, apex left; D34, D35, apex posterior; D36, D37, apex right; D38-D49, sections of the three cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

IHPAA Discrepancy		/

Source: NCI Genomic Data Commons file fd29d14e-32a9-4aea-8cb2-54a848ee9757 (TCGA-KK-A8IA.641BD2CD-8B57-49BB-A2E1-9EB78097B4D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).